Somatic mutation profile of tumor specimen TCGA-TS-A7P6-01A (aliquot TCGA-TS-A7P6-01A-21D-A34C-32) from TCGA case TCGA-TS-A7P6, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 61.2 years (22,338 days).
Specimen TCGA-TS-A7P6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 155f92f0-98ce-44a1-88e2-9078ac132342.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TS-A7P6-10A (Blood Derived Normal), aliquot TCGA-TS-A7P6-10A-01D-A34C-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/54f69789-a30a-4b78-b68e-1e7cac8bafac

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 4, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMOTL1 | c.1198G>A p.G400R | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.707); catalogued as rs377110840; called by muse, mutect2, varscan2
- ATP13A1 | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as rs964376537; called by muse, mutect2, varscan2
- CHST6 | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754243926; called by muse, mutect2, varscan2
- DDX54 | c.1076C>T p.T359M | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as rs549423905, COSV100013903; called by muse, mutect2, varscan2
- LMO4 | c.343T>A p.C115S | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104423791; called by muse, mutect2, varscan2
- OXA1L | c.8C>A p.T3K | Missense Mutation (SNP) | VAF 34/118 reads (29%) | PolyPhen benign (0.001); catalogued as COSV53538191; called by muse, mutect2, varscan2
- PCLO | c.5729C>T p.A1910V | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs375287995; called by muse, mutect2, varscan2
- PPP6R1 | c.1462C>T p.R488W | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as rs751516737; called by muse, mutect2, varscan2
- ACSL4 | c.1312A>G p.M438V (on ENST00000340800 / NM_022977.2; = p.M397V on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COL22A1 | c.3446A>G p.K1149R | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR10H3 | c.357G>T p.M119I | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- PRKACG | c.977G>C p.S326T | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- RIMBP2 | c.2324G>C p.R775T | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SBF2 | c.1919C>T p.A640V | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); called by muse, mutect2
- ACSF2 | c.441G>A p.A147= | Silent (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2
- MEOX2 | c.900G>A p.E300= | Silent (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2
- RALGAPA1 | c.1107T>C p.N369= | Silent (SNP) | VAF 7/27 reads (26%) | called by muse, mutect2, varscan2
- TEX15 | c.6858T>C p.N2286= (on ENST00000256246; = p.N2669= on NM_001350162.2) | Silent (SNP) | VAF 33/96 reads (34%) | called by muse, mutect2, varscan2
- GLOD4 | c.146-85A>G | Intron (SNP) | VAF 11/30 reads (37%) | called by muse, mutect2, varscan2
